Somatic mutation profile of tumor specimen TCGA-HT-7858-01A (aliquot TCGA-HT-7858-01A-11D-2395-08) from TCGA case TCGA-HT-7858, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 28.5 years (10,422 days).
Specimen TCGA-HT-7858-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c23b394f-bcce-4945-9815-eeb5f3fde44b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7858-10A (Blood Derived Normal), aliquot TCGA-HT-7858-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ce50562-21c7-4e4f-89b7-bf6ce53df830

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 35/52 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CACNG8 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV54413933; called by muse, mutect2, varscan2
- CNOT1 | c.6178-1G>T p.X2060_splice | Splice Site (SNP) | VAF 7/65 reads (11%) | catalogued as COSV55313988; called by muse, mutect2
- DSC3 | c.2663C>G p.T888R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV64572096, COSV64576192; called by muse, mutect2, varscan2
- DSCAM | c.1520T>G p.I507S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV68022484; called by muse, mutect2, varscan2
- GZF1 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57635153; called by muse, mutect2, varscan2
- HOXA1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.747); catalogued as COSV56065451, COSV56067351; called by muse, mutect2, varscan2
- IPO13 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV64893930; called by muse, mutect2
- SRBD1 | c.2146G>A p.V716I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs752155294, COSV55396663; called by muse, mutect2, varscan2
- ATRX | c.1208del p.K403Rfs*11 | Frame Shift Del (DEL) | VAF 154/302 reads (51%) | called by mutect2, pindel, varscan2
- CD300LB | c.258G>A p.T86= | Silent (SNP) | VAF 71/234 reads (30%) | catalogued as rs763129538, COSV58725218; called by muse, mutect2, varscan2
- CYTH1 | c.684G>A p.P228= | Silent (SNP) | VAF 45/258 reads (17%) | catalogued as rs201122386, COSV63118963; called by muse, mutect2, varscan2
- FYB1 | c.6G>A p.A2= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs774770343, COSV60942303; called by muse, mutect2, varscan2
- MTMR3 | c.2874C>T p.C958= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs147400483; called by muse, mutect2, varscan2
- OR6C2 | c.756C>T p.S252= | Silent (SNP) | VAF 5/121 reads (4%) | catalogued as COSV100498712; called by muse, mutect2
- SSPOP | n.2569G>A | RNA (SNP) | VAF 9/23 reads (39%) | catalogued as rs1317413286, COSV50486722; called by muse, mutect2, varscan2
